Somatic mutation profile of tumor specimen TARGET-40-PALECC-01A (aliquot TARGET-40-PALECC-01A-01D) from TARGET case TARGET-40-PALECC, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Age at diagnosis: 10.0 years (3,661 days).
Specimen TARGET-40-PALECC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 154c5aaf-61c8-4eab-abe2-f316e97d9a76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PALECC-10A (Blood Derived Normal), aliquot TARGET-40-PALECC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a88e9fb9-602a-4b23-9056-b3ea65c36d90

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 2, 3'UTR 1, Splice Region 1, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CABIN1 | c.2974G>T p.E992* | Nonsense Mutation (SNP) | VAF 11/97 reads (11%) | catalogued as COSV99573969; called by muse, mutect2, varscan2
- CACNA2D3 | c.1090G>T p.A364S | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55574289; called by muse, mutect2, varscan2
- FAT2 | c.6746C>T p.A2249V | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.416); catalogued as COSV99941352; called by muse, mutect2
- GLYATL3 | c.485C>A p.A162E | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1453059002, COSV100966291; called by muse, mutect2, varscan2
- IGF1R | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.165); catalogued as rs148662051, CM110090, COSV51274044; called by muse, mutect2, varscan2
- PCNX3 | c.2356C>T p.R786W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1336656751; called by muse, mutect2, varscan2
- UNC13A | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.059); catalogued as rs868832101, COSV53201613; called by muse, mutect2, varscan2
- ITIH6 | c.3601C>G p.L1201V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.117); called by muse, mutect2
- MAPK7 | c.2298C>T p.G766= | Splice Region (SNP) | VAF 18/418 reads (4%) | called by muse, mutect2
- MIB1 | c.2987G>A p.R996H | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- OR8B2 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.671); called by muse, mutect2
- TFEB | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 56/368 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WBP2NL | c.536C>A p.P179H | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.105); called by muse, mutect2
- HRC | c.1971+11A>G | Intron (SNP) | VAF 17/59 reads (29%) | called by muse, mutect2, varscan2
- PPIAP58 | chr19:29923660 C>A | 3'Flank (SNP) | VAF 28/92 reads (30%) | called by muse, mutect2, varscan2
- SLC25A45 | c.*264C>G | 3'UTR (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- TREM1 | c.406+15A>T | Intron (SNP) | VAF 21/132 reads (16%) | called by muse, mutect2, varscan2
